Gene-level copy-number profile of tumor specimen TCGA-DD-AAE4-01A from TCGA case TCGA-DD-AAE4, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 49.3 years (18,009 days).
Specimen TCGA-DD-AAE4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.92e96e5e-38ad-4a74-88cc-726f3f49c050.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AAE4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9167d5ae-c4e6-4160-b49f-02e68fbdf7d6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,139; copy number 2: 52,793; copy number 3: 2,870; copy number 4: 7; copy number 5: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AAE4-01A-11D-A40Q-01): tumor purity 0.79, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:169,511,951–169,894,267, 9 genes, copy number 5 (within-gene range 3–5): F5, SELP, C1orf112, SELL, SELE, AL021940.1, METTL18, SCYL3, RN7SL333P.

Autosomal genes at a single copy (total copy number 1): 4,139. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
